Gene-level copy-number profile of tumor specimen HCM-CSHL-0242-C18-01B from HCMI case HCM-CSHL-0242-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.1 years (26,343 days).
Specimen HCM-CSHL-0242-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 47bb5b29-fa9b-4a29-acc1-4e27bafce257.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0242-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/1b1b7c00-cff4-4e83-a355-f45fbc3fef4d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 7; copy number 2: 2,899; copy number 3: 1,692; copy number 4: 48,166; copy number 5: 2,383; copy number 6: 3,710; copy number 7: 34; copy number 8: 9; copy number 9: 2; copy number 11: 1; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:155,611,231–155,781,485, 2 genes, copy number 9: AC009403.1, RBM33.
- chr8:144,012,280–144,051,522, 2 genes, copy number 11–14 (within-gene range 4–14): SPATC1, SMPD5.

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
